Somatic mutation profile of tumor specimen TCGA-XK-AAJR-01A (aliquot TCGA-XK-AAJR-01A-11D-A41K-08) from TCGA case TCGA-XK-AAJR, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.0 years (22,643 days).
Specimen TCGA-XK-AAJR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99a26324-a84f-4205-b20c-2ba50c20e301.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XK-AAJR-10A (Blood Derived Normal), aliquot TCGA-XK-AAJR-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c143871-cf4a-4e1e-babf-738ebf631f8f

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 11, Silent 11, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALS2CL | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV100015197; called by muse, mutect2, varscan2
- ATP13A5 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.438); catalogued as rs776379818, COSV60870321; called by muse, mutect2, varscan2
- ATP1A3 | c.3025A>G p.K1009E (on ENST00000545399 / NM_001256214.2; = p.K996E on NM_152296.5) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100132420; called by muse, mutect2, varscan2
- CCDC150 | c.426A>G p.I142M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.904); catalogued as COSV99777166; called by muse, mutect2, varscan2
- FMO1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100707854; called by muse, mutect2
- GCOM1 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV99985125; called by muse, mutect2, varscan2
- GZMH | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV99362005; called by muse, mutect2, varscan2
- LRPAP1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 59/431 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs746310452, COSV99579054; called by muse, mutect2, varscan2
- MOGAT1 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as rs185619677; called by mutect2, varscan2
- MYH3 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV99878532; called by muse, mutect2, varscan2
- NBN | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99619826; called by muse, mutect2, varscan2
- SMARCC1 | c.2759T>A p.I920N | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424173632, COSV54379416, COSV99593183; called by muse, mutect2, varscan2
- TRANK1 | c.7405A>T p.K2469* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100083797; called by muse, mutect2, varscan2
- TRMT44 | c.1311-1G>A p.X437_splice | Splice Site (SNP) | VAF 12/115 reads (10%) | catalogued as COSV101077794; called by muse, mutect2, varscan2
- C1orf127 | c.2298del p.T767Qfs*27 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- CPLX4 | c.148_150delinsTA p.K50Yfs*3 | Frame Shift Del (DEL) | VAF 20/161 reads (12%) | called by pindel, varscan2*
- KMT2D | c.2972_2981delinsGT p.T991Sfs*74 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by pindel, varscan2*
- PCF11 | c.1786dup p.R596Kfs*10 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.10325del p.P3442Qfs*43 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- ABCD2 | c.1098T>G p.T366= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as rs1197997210, COSV100429657; called by muse, mutect2, varscan2
- BEST2 | c.186C>T p.F62= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs772723089, COSV50361444, COSV99244684; called by muse, mutect2
- BOD1L1 | c.2205G>A p.S735= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs201716332; called by muse, mutect2, varscan2
- COL7A1 | c.1008G>A p.Q336= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100096944; called by muse, mutect2, varscan2
- CYSLTR1 | c.408A>C p.T136= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100964745; called by muse, mutect2, varscan2
- GPR158 | c.2500C>T p.L834= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV100894004; called by muse, mutect2
- GRIA1 | c.945T>G p.S315= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99601091; called by muse, mutect2, varscan2
- PBRM1 | c.756A>C p.I252= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV99969947; called by muse, mutect2
- POLQ | c.1824G>T p.V608= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1192503662, COSV51750321, COSV99952565; called by muse, mutect2, varscan2
- PTPN21 | c.120C>T p.S40= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs1302519963, COSV100161952; called by muse, mutect2, varscan2
- ZNF701 | c.324G>A p.R108= (on ENST00000301093; = p.R42= on NM_018260.3) | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV99990935; called by muse, mutect2
